Gene-level copy-number profile of tumor specimen ALCH-B38F-TTP1-A from ALCHEMIST case ALCH-B38F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.3 years (24,226 days).
Specimen ALCH-B38F-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 70f4441a-93c6-441a-85dc-501bdaea057a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B38F-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/ecdfa7b3-9589-433a-8cdc-1915f3e7a6c0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 225; copy number 1: 2,703; copy number 2: 52,358; copy number 3: 2,986; copy number 4: 108; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 209 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,009,982–91,880,195, 90 genes (within-gene range 0–2) (broad region; genes not listed).
- chr2:131,491,160–131,536,988, 4 genes (within-gene range 0–2): MIR4784, SMPD4BP, CCDC74A, MED15P4.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr3:53,064,283–53,130,453, 2 genes (within-gene range 0–2): SERBP1P3, RFT1.
- chr3:75,415,070–75,542,929, 6 genes (within-gene range 0–1): ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, RPS3AP15.
- chr3:129,954,105–130,201,336, 13 genes: AC083906.3, TRH, AC083906.1, AC083906.2, OR7E129P, OR7E21P, AC083906.4, ALG1L2, LINC02014, FAM86HP, LINC02021, ENPP7P3, SNRPCP8.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr12:111,304,142–111,403,310, 5 genes (within-gene range 0–2): MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14.
- chr14:18,333,726–18,596,310, 8 genes (within-gene range 0–2): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr16:46,469,341–46,790,407, 13 genes (within-gene range 0–2): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3.
- chr16:75,204,103–75,228,197, 3 genes (within-gene range 0–2): CTRB2, CTRB1, AC009078.2.
- chr19:24,004,358–27,794,005, 11 genes (within-gene range 0–2): RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr21:8,701,461–13,120,807, 46 genes: CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:120,336,413–120,489,937, 2 genes, copy number 5: ARHGEF12, 7SK.
- chr15:92,805,770–92,809,057, 2 genes, copy number 5 (within-gene range 2–5): AC106028.2, AC106028.4.

Autosomal genes at a single copy (total copy number 1): 2,679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
